TCGA case TCGA-2G-AALC — Testicular Germ Cell Tumors (TCGA-TGCT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Germ Cell Neoplasms; Primary site: Testis. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1e0970c0-af70-4aaf-b11d-c51fcd769b33

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Netherlands; Age at index: 34 years; Year of birth: 1978; Vital status: Alive.

Diagnoses (1)
1. Embryonal carcinoma, NOS: ICD-O-3 morphology code: 9070/3; ICD-10 code: C62.9; Tissue or organ of origin: Testis, NOS; Site of resection or biopsy: Testis, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 34.4 years (12,554 days); Year of diagnosis: 2012; Method of diagnosis: Orchiectomy; AJCC staging edition: 7th; AJCC clinical T: T2; AJCC clinical N: N1; AJCC clinical M: M1a; AJCC clinical stage: Stage IIIA; AJCC pathologic T: T2; AJCC pathologic N: NX; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; IGCCCG stage: Intermediate Prognosis; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 842 days (2.3 years); Ajcc serum tumor markers: S3; Sites of involvement: Rete Testis.
   Pathology details: Intratubular germ cell neoplasia present: Yes; Lymphatic invasion present: Yes; Vascular invasion present: Yes.
   Pathology details: Lymph node dissection site: Retroperitoneal; Lymph nodes removed: No; Timepoint category: Postoperative.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Bleomycin + Cisplatin + Etoposide; Treatment intent type: Adjuvant; Days to treatment start: 3 days; Days to treatment end: 76 days; Treatment outcome: Partial Response.
   Treatment given: Treatment type: Surgery, NOS; Treatment anatomic sites: Testis.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (4 entries)
- Days to follow up: 506 days (1.4 years); Disease response: Tumor Free.
- Days to follow up: 590 days (1.6 years); Disease response: Tumor Free.
- Days to follow up: 842 days (2.3 years); Disease response: Tumor Free.
- Karnofsky performance status: 80; ECOG performance status: 1; Timepoint: Follow-up.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 0: Lactate Dehydrogenase 1173; Alpha Fetoprotein 148; Human Chorionic Gonadotropin 160.
- Day 3: Lactate Dehydrogenase 859; Alpha Fetoprotein 150; Human Chorionic Gonadotropin 119.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Fertility history: Conceived 1 or more children by natural conception; Risk factors: Undescended Testis; Undescended testis corrected: Yes; Undescended testis corrected age range: 10-14 years; Undescended testis corrected laterality: Left; Undescended testis corrected method: Orchiopexy; Undescended testis history: Yes; Undescended testis history laterality: Left.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-2G-AALC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 300 mg.
  Slide TCGA-2G-AALC-01A-01-TSA: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 25; Percent lymphocyte infiltration: 8; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 3.
- Sample TCGA-2G-AALC-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-2G-AALC-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
